Surgical pathology report (de-identified scan), TCGA case TCGA-69-7973, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-69-7973-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED] / F

SPECIMEN SUBMITTED:

Part A: 4L

Part B: 7

Part C: 4R

Part D: 2R

Part E: R12

Part F: RIGHT MIDDLE LOBE

Part G: RIGHT LOWER LOBE MARGIN

Part H: RIGHT MIDDLE LOBE
PULMONARY ARTERIAL MARGIN

Part I: RIGHT MIDDLE LOBE BRONCHIAL
MARGIN

Part J: RIGHT MIDDLE LOBE
PULMONARY VEIN MARGIN

Part K: R11

Part L: R12

Part M: LEVEL 7

Part N: 4R

Part O: RIGHT MIDDLE LOBE
ADDITIONAL LOWER LOBE MARGINS

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Final Diagnosis

1. Lymph nodes, 4L, 7, 4R, 2R, R12, excision (A-E) - Lymph nodes with anthracosis negative for neoplasm.
2. Right lung, middle lobe, lobectomy (F) - Adenocarcinoma with solid (60%), acinar (20%) and cribriform (20%) patterns.
- Centrilobular emphysema.
3. Right lung, lower lobe, margin, excision (G) - Detached cluster of malignant cells consistent with adenocarcinoma.
4. Right lung, middle lobe, pulmonary arterial margin, excision (H) - Atypical cells of uncertain clinical significance present in lumen.
5. Lung, middle lobe, bronchial margin, excision (I) - Segment of bronchial wall with no diagnostic alterations.
6. Right lung, middle lobe, pulmonary vein margin, excision (J) - Detached cluster of atypical cells of uncertain clinical significance.
7. Lymph node, R11, R12, level 7, 4R, excision (K-N) - Lymph nodes with anthracosis, negative for neoplasm.
8. Lung, middle lobe, additional lower lobe margin, excision (O) - Lung parenchyma, negative for neoplasm.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

2. An immunohistochemical panel was performed revealing that the tumor cells are positive for CAM 5.2 and TTF-1. Focal positivity is noted with synaptophysin. Tumoral cells are negative for chromogranin, p63, and CD56. Mitotic activity is approximately 7 mitoses per 10 high-power field. The morphologic findings along with immunohistochemical profile are in keeping with an adenocarcinoma of the lung. Clear cell change and focal signet ring cell patterns, as can be seen in lung adenocarcinomas, are present. This tumor will be sent for EGFR mutational analysis and the results of those studies reported as an addendum.

Tumor Location: Right middle lobe

Tumor Size: 4.1 x 4 x 3.7 cm

Vascular Invasion: Absent

Lymphatic Invasion: Absent

Bronchial Margin: Negative

Vascular Margin: Rare clusters of tumor cells are present in the perivascular soft tissue of the pulmonary vein margin (Part J) but not within the vessel lumen. The pulmonary artery margin of excision (Part H) contains atypical cells within the lumen but this is interpreted as negative.

Parenchymal Margins: The final lower lobe margin of excision is negative for neoplasm (Part O).

Pleura/Soft Tissue Margin: Negative

Pathologic Stage (AJCC): pT2a N0, Stage IB.

GENERAL COMMENT

Part H and J: Both of these specimens contain detached clusters of atypical cells. The cells in Part H are present within a lumen of the vessel and the cells in Part J are outside of the vessel in a detached cluster. In neither case is there definitive neoplasm present in the frozen section slide. These margins are interpreted as negative for neoplasm.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [REDACTED]
[REDACTED] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: EGFR Mutation Analysis Re

Status: Ordered

Text: {Not Entered}

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

- A. Negative for tumor
- B. Negative for carcinoma
- C. Negative for carcinoma
- D. Negative for carcinoma
- E. Negative for carcinoma
- F. Vascular margin designated by the surgeon - negative for tumor
- G. Atypical cells present, suspicious for cancer
- H. Atypical cells present in lumen of uncertain clinical significance
- I. Negative for tumor
- J. Negative for tumor
- O. Negative for tumor

Clinical Diagnosis:

LUNG CA

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh at the frozen desk, labeled [REDACTED] is a 0.8 x 0.5 x 0.3 cm single piece of black-brown nodule. The specimen is totally submitted for frozen section in A1.

B. Received fresh at the frozen desk labeled [REDACTED] are multiple fragments of tan-black soft tissue measuring 2 x 1.9 x 0.4 cm in aggregate. Representative sections are submitted for frozen section in one cassette labeled B1. The remainder is totally submitted for permanent sections in one cassette labeled B2.

C. Received fresh at the frozen desk, labeled [REDACTED] is a 0.9 x 0.5 x 0.3 cm black-brown soft tissue fragment. The specimen is totally submitted for frozen section in one cassette labeled C1.

D. Received fresh at the frozen desk, labeled [REDACTED] is a 1.6 x 1.7 x 0.4 cm soft tissue fragment. The specimen is totally submitted in one cassette labeled D1.

[REDACTED] [REDACTED]

E. Received fresh at the frozen desk is a specimen labeled [REDACTED]. It consists of a single piece of brown-red nodule that measures 0.7 x 0.5 x 0.3 cm. Totally submitted for frozen section in cassette E1.

F. Received in formalin labeled [REDACTED] is a 104.1 gram lobectomy specimen of the middle lobe of the right lung (10.5 x 6.0 x 4.3 cm) and bronchial remnant (0.3 cm in length and 0.5 cm in diameter). A suture line is removed and the parenchyma is inked orange. The pleural surface is inked blue. A 4.1 x 4 x 3.7 cm poorly circumscribed firm gray-white mass is identified at <0.1 cm from the pleura, 0.2 cm from the parenchymal margin, 0.3 cm from the bronchial margin. The tumor causes retraction of the overlying pleura, but does not grossly invade through the pleura, which has a smooth and glistening surface. There is a fibrous pleural scar with pleural detachment (3.5 x 3 x 0.2 cm) extending to the resection margin. A firm dark brown area of parenchymal consolidation is present adjacent to the tumor. Also, received is a 2.5 x 1.2 x 1 cm additional piece of white-tan tissue. Representative sections are submitted as follows: F1 frozen section of vascular margin stained with Diff-Quick, F2 bronchial margin, F3 additional vascular margins, F4-F6 tumor in relation to pleural surface (area of retraction), F7-F8 tumor in relation to parenchymal margin of resection and pleural surface with area of fibrosis, F9 tumor in relation to bronchus, F10 tumor in relation to vessels, F11 tumor with uninvolved parenchyma, F12 uninvolved parenchyma, F13 parenchyma with area of consolidation, F14 representative section of additional segment.

G. Received fresh at the frozen desk is a specimen labeled [REDACTED]. It consists of multiple fragments of red-brown soft tissue that measures in aggregate 1.2 x 0.9 x 0.3 cm. The specimen is totally submitted for frozen section evaluation in cassette G1.

H. Received fresh at the frozen desk is a specimen labeled [REDACTED]. It consists of a single piece of vessel with lumen that measures 0.6 x 0.4 x 0.3 cm. The specimen is totally submitted for frozen section evaluation in cassette H1.

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Gross Description:

I. Received fresh at the frozen desk is a specimen labeled [REDACTED] It consists of a single piece of bronchus that measures 1.4 x 0.9 x 0.4 cm. The specimen is totally submitted for frozen section in cassette I1.

J. Received fresh at the frozen desk is a specimen labeled [REDACTED] It consists of a single piece of vascular margin that measures 0.3 x 0.3 x 0.3 cm. The specimen is totally submitted for frozen section evaluation as J1.

K. Received fresh is a tan-gray nodule resembling a lymph node measuring 0.9 x 0.4 x 0.3 cm. Totally submitted in one cassette.

L. Received fresh are four tan-gray nodules resembling lymph nodes ranging in size from 0.3 to 1.0 cm. The largest nodule is totally submitted in L1. The remaining three nodules are totally submitted in L2. Also received in the same container are segments of tan soft membranous tissue measuring 1.6 x 1.2 x 0.2 cm. The larger segment of soft tissue is sectioned into three pieces and totally submitted in L3. The smaller membranous segment of tissue is sectioned into two pieces and totally submitted in L4.

M. Received in formalin are four tan-gray nodules resembling lymph nodes ranging in size from 0.3 to 2.1 cm. The largest nodule is totally submitted in M1. The second largest nodule is totally submitted in M2. The remaining two nodules are totally submitted in M3.

N. Received fresh are three tan-gray nodules resembling lymph nodes ranging in size from 0.3 to 2.5 cm. The largest nodule is bisected and totally submitted in N1-N2. The second largest nodule is totally submitted in N3. The smallest nodule is totally submitted in N4.

O. The specimen is received fresh at the frozen desk labeled [REDACTED] and consists of a 3.5 x 1 x 0.6 cm segment of lung parenchyma with two staple lines. After removing the staple lines, the specimen is totally submitted for frozen section in O1.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 44b808bd-d6a1-4eff-9309-5f317d7cf086 (TCGA-69-7973.FD1B94D4-D5B9-47FE-96AD-4E3D781A638A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).